Surgical pathology report (de-identified scan), TCGA case TCGA-EQ-8122, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-EQ-8122-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

Phone [REDACTED]

Revised Surgical Pathology Report

Procedure: [REDACTED]

Reason for revision: [REDACTED] requested clarification of the lymph node count.

Diagnosis

A. Subtotal distal gastrectomy, perigastric lymph nodes and omentum, resection:

Adenocarcinoma, intestinal type, poorly differentiated
Tumor focally invades subserosal connective tissue (pT3)
Metastatic adenocarcinoma in 2 of 19 lymph nodes (pN1)
Resection margins negative for tumor
Background of moderate acute and chronic gastritis with intestinal metaplasia.

Immunohistochemical stain is negative for Helicobacter pylori

B. Hepatic artery lymph node, biopsy:

Single lymph node negative for metastatic tumor.
Benign adipose tissue

C. Portal vein lymph node, biopsy:

2 lymph nodes negative for metastatic tumor (0/2)
Benign adipose tissue

D. Splenic artery lymph node, biopsy:

4 lymph nodes negative for metastatic tumor (0/4).
Benign adipose tissue

Microscopic Description:

Microscopic examination performed.

A. Template summary of partial gastrectomy-

Histologic type: Adenocarcinoma, intestinal type

Histologic grade: Poorly differentiated

Tumor size: 7.4 x 4.5 x 1.6 CM

Primary tumor (pT): Tumor invades through the muscular wall focally in A6. (pT3)

Proximal margin: Negative

Distal margin: Negative

Radial margin: Negative

Distance of tumor from closest margin: 2 cm from distal margin

Vascular invasion: Not identified

Regional lymph nodes (pN): 2 of 19 regional lymph nodes positive for metastatic tumor. One positive lymph node is from the lesser curvature and one is from the greater curvature. Largest metastatic focus is 4 mm (pN1)

Distant metastasis (pM): Not evaluated (pMX)

Other findings: There is background moderate acute and chronic gastritis with intestinal metaplasia. No Helicobacter pylori organisms were identified by immunohistochemical stain.

B. Separately submitted lymphnodes were all negative for tumor.

Specimen

A. Subtotal distal gastrectomy, perigastric lymph nodes, and omentum

B. Hepatic artery lymph nodes

C. Portal vein lymph node

D. Splenic artery lymph node

[page 2 of 2]
Clinical Information

Gastric cancer

Procedure is a subtotal gastrectomy please count 15 lymph nodes

Gross Description

A. Received fresh is an unopened distal gastrectomy which measures 20 cm along the greater curvature, 13 cm along the lesser curvature, and 4.5 cm from anterior to posterior. The serosa is smooth tan-pink with an area of retraction and focal induration at the distal end (subsequently inked blue). A scant amount of attached perigastric fat and a copious amount of unremarkable omentum are received in association with the specimen. The proximal and distal margins measure 17.0 and 4.4 cm in circumference respectively. Both margins are secured by a staple line which is subsequently removed. On opening, there is a 7.4 x 4.5 cm rubbery tan-white-to red tumor mass within the distal portion of the specimen with raised rolled edges. The tumor is located 2 cm from the distal margin (following removal of the staple line) in the fresh state. A portion of tumor and a portion of normal gastric mucosa are submitted for tissue procurement as requested. On sectioning, the tumor has a maximal thickness of 1.6 cm, extending to within 0.3 cm of the inked serosal surface the remaining gastric mucosa is tan-pink with regular folds and the wall averages 0.8 cm. Several slightly rubbery white pink tissues in keeping with lymph nodes measuring up to 1.3 cm in greatest dimension are recovered as follows: 9 along the lesser curvature and 14 along the greater curvature. RS 18
Summary: 1 - perpendicular sections proximal margin; 2 through 4 - perpendicular sections to tumor to distal margin (inked orange); 5 through 8 - tumor to inked serosal surface; 9 - tumor to proximal normal mucosa; 10 and 11 - random normal; 12 - 5 lymph nodes lesser curve; 13 - 4 lymph nodes lesser curve; 14 - 6 lymph nodes greater curve; 15 - 5 lymph nodes greater curve; 16 through 18 - one bisected lymph node per cassette greater curve

B. Received fresh labeled "hepatic artery lymph nodes" is a 3.0 x 2.3 x 1.4 cm portion of soft, lobulated tan gold adipose tissue. A single, 1.4 cm tan to red tissue in keeping with lymph node is recovered. AS3
Summary: 1 - bisected lymph node; 2 and 3 - residual adipose tissue

C. Received fresh labeled "portal vein lymph node" is a 1.5 cm soft tan-red tissue in keeping with lymph node with a moderate amount of associated adipose tissue. AS 2
Summary: 1 - bisected lymph node; 2 - residual adipose tissue.

D. Received fresh labeled "splenic artery lymph node" is a 4.4 x 2.9 x 1.5 cm portion of soft, lobulated tan gold adipose tissue. Two slightly rubbery tan-red tissues in keeping with lymph nodes measuring 0.5 and 0.9 cm in greatest dimension are recovered. AS 4
Summary: 1 - one lymph node; 2 - one bisected lymph node; 3 and 4 - residual adipose tissue

Source: NCI Genomic Data Commons file d933a788-33df-4c05-b5e4-348878e40a37 (TCGA-EQ-8122.C8C33BD6-B0ED-474F-AFA7-E46D0EDB03FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).